Gene-level copy-number profile of tumor specimen TCGA-HZ-7925-01A from TCGA case TCGA-HZ-7925, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 66.1 years (24,150 days).
Specimen TCGA-HZ-7925-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.b828f4f6-905a-46f6-b50f-b7289ec9cbec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-7925-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a07e681-5579-4bce-8873-5710daab2e01

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 9,381; copy number 2: 44,275; copy number 3: 5,420; copy number 4: 563; copy number 5: 35; copy number 6: 85; copy number 7: 26; copy number 12: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-7925-01A-11D-2153-01): tumor purity 0.25, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 172 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:30,388,935–34,048,949, 85 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr21:31,347,736–34,615,113, 87 genes, copy number 5–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,346. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
